Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A95X, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A95X-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Reviewed (initials)	Date Reviewed: 12/20/13	

Specimen(s) Received:

- 1: LESION RIGHT LOWER LIP
- 2: PRIMARY MELANOMA RIGHT BACK
- 3: MELANOMA RIGHT AXILLA

2CD-0-3
Melanoma NOS 8720/3
Site: Soft tissue axilla 1493
JW 5/16/14

FINAL DIAGNOSIS

1) LIP, RIGHT LOWER, EXCISIONAL BIOPSY:

- VENOUS LAKE
- NEGATIVE FOR MALIGNANCY

2) SKIN, RIGHT BACK, EXCISION:

- METASTATIC MELANOMA, COMPLETELY REPLACING A LYMPH NODE WITHIN THE SUBCUTANEOUS FAT
- RESECTION MARGIN, NEGATIVE FOR MALIGNANCY

3) SOFT TISSUE, RIGHT AXILLA, EXCISION:

- LARGE NODULE OF METASTATIC MELANOMA WITHIN SOFT TISSUES
- THERE IS FOCAL NECROSIS EN MASSE
- THE MARGINS ARE POSITIVE

Pathologist:

* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

- 1) Received fresh, labeled with the patient's name and "lesion right lower lip" is an unoriented 1.2 x 0.8 cm gray-pink lip

[page 2 of 2]
ellipse excised to a depth of 0.6 cm. There is a 0.2 x 0.1 cm ill-defined irregular hyperpigmented area which is as close as 0.1 cm from the closest resection margin visible on the skin surface. The entire resection margin is inked blue and the specimen is serially sectioned to reveal a 0.4 x 0.4 x 0.5 cm black ill-defined lesion that comes within 0.1 cm of the resection margin. Gross photographs are taken. The specimen is entirely submitted as follows: cassette #1=tips and cassette #2=central portion

2) Received fresh, labeled with the patient's name and "primary melanoma right back" is a 5.8 x 2.5 cm unoriented tan-white skin ellipse excised to a depth of 3.5 cm. There is a 3.4 cm linear defect on the skin surface which is marked with orange ink. Representing the area that Dr. removed tumor tissue for research purposes. No distinct lesion is noted on the skin surface. The entire resection margin is inked blue and the specimen is serially sectioned to reveal a 1.5 x 1.3 x 1.8 cm circumscribed white-pink homogenous lesion in the subcutaneous tissue and is as close 0.1 cm from the closest resection margin. Gross photographs are taken. Representative section are submitted as follows: cassette #1=tips and cassettes #2-13=per diagram.

3) Received fresh, labeled with the patient's name and "melanoma right axilla" is a 8 x 4.5 x 3.5 cm gray-pink irregular unoriented piece of soft tissue mass. There is a 4 cm linear incision on the surface of the specimen which is inked orange corresponding with the area where Dr. removed tumor tissue for research purposes. The entire surface is inked blue and the specimen is serially sectioned to reveal a 4.5 x 3.4 x 3.3 cm irregular but circumscribed white-pink mass lesion. The lesion displays focal hemorrhagic changes and grossly abuts the resection margin. The mass is surrounded by yellow fibroadipose tissue. Gross photographs are taken. Representative sections are submitted in six cassettes per diagram.

Summary of Stains Performed and Reviewed

	Count
HMB-45 *	2
Negative Control *	2
S-100 Protein *	2

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the supplier. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and Internal controls stained appropriately.

Summary of Tissue Submitted for Microscopic Examination

	# Blocks	Block Detail		
		Designation	#	Description
Part 1] LESION RIGHT LOWER LIP	2	[Undes]	(1)	(No Description)
		TIPS	(1)	(No Description)
Part 2] PRIMARY MELANOMA RIGHT BACK	13	[Undes]	(12)	(No Description)
		TIPS	(1)	(No Description)
Part 3] MELANOMA RIGHT AXILLA	6	[Undes]	(6)	(No Description)
Total:	21			

Source: NCI Genomic Data Commons file aa7840b1-932a-4d39-8977-2d8f032618d0 (TCGA-DA-A95X.0B5B3212-7704-4CF4-BE35-E922F8A66670.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).